CCDI case PBCLIU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Bones, joints and articular cartilage of limbs.
https://portal.gdc.cancer.gov/cases/373070b8-632f-41ba-a970-b44f96630ee1

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Ewing sarcoma: ICD-O-3 morphology code: 9260/3; Tissue or organ of origin: Lower limb, NOS; Age at diagnosis: 15.5 years (5,651 days).

Biospecimens (3 samples)
- Sample 0DUKGT: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DUKHA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DUKIU: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
